Surgical pathology report (de-identified scan), TCGA case TCGA-F4-6459, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Asterand, specimen TCGA-F4-6459-01A (Primary Tumor).

		LARGE INTESTINE TISSUE CHECKLIST Specimen type: Colectomy Specimen size: Not specified Tumor site: Sigmoid colon Tumor size: 5 x 4 x 1 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Pericolonic tissues Lymph nodes: 6/6 positive for metastasis (Intraabdominal 6/6) Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None
--	--	--

--

Source: NCI Genomic Data Commons file d8ba8024-7154-4037-b006-d79edefea297 (TCGA-F4-6459.D0F0EEF4-BC4D-47E6-A4B6-C0F5D48C6203.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).